Somatic mutation profile of tumor specimen TCGA-AA-3837-01A (aliquot TCGA-AA-3837-01A-01W-0900-09) from TCGA case TCGA-AA-3837, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.5 years (24,655 days).
Specimen TCGA-AA-3837-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0163183f-26ff-48e0-ac65-687173ab1e99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3837-10A (Blood Derived Normal), aliquot TCGA-AA-3837-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6367fc2-4a7a-4051-82bc-6ccdd36c5b8a

The open-access MAF lists 159 somatic variants for this specimen: 117 protein-altering or splice-affecting, 42 silent.
By variant classification: Missense Mutation 93, Silent 42, Nonsense Mutation 8, Frame Shift Ins 6, Frame Shift Del 4, Splice Region 2, Splice Site 2, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 45/147 reads (31%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.860A>T p.E287V (on ENST00000281708 / NM_001349798.2; = p.E207V on NM_018315.5) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55897632; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 37/214 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 44/98 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039551, CM060085, CM086981, COSV55445539, COSV55457221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.7967C>T p.A2656V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375861638; called by muse, mutect2, varscan2
- ABCC11 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62321209, COSV62321743; called by muse, mutect2
- AGTR1 | c.924dup p.F309Ifs*2 | Frame Shift Ins (INS) | VAF 69/158 reads (44%) | catalogued as rs1205343354; called by mutect2, pindel, varscan2
- AP3B1 | c.1891A>C p.T631P | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54877851; called by muse, mutect2, varscan2
- ARL13B | c.897G>C p.E299D (on ENST00000394222 / NM_001174150.2; = p.E192D on NM_144996.4) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs1365708562, COSV57396785; called by muse, mutect2, varscan2
- ASAH2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV61482693; called by muse, mutect2, varscan2
- ATP2A1 | c.1413C>A p.C471* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV63920211; called by muse, mutect2, varscan2
- BARHL2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV64980934; called by muse, mutect2, varscan2
- C7orf33 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs775386548, COSV61022855, COSV61023427; called by muse, mutect2, varscan2
- CAPN1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs748491783, COSV54196856; called by muse, mutect2, varscan2
- CCR1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as rs1380953868, COSV56121634; called by muse, mutect2, varscan2
- CDH22 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs759577757, COSV64836788; called by muse, mutect2, varscan2
- CEP85L | c.1617G>T p.K539N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs1404682181, COSV63821157; called by muse, mutect2, varscan2
- COL1A2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51954486, COSV51962001; called by muse, mutect2, varscan2
- COL2A1 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1462514936, COSV61528660; called by muse, mutect2, varscan2
- CYB5R3 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs370695594; called by muse, mutect2, varscan2
- CYP4B1 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54721820, COSV99596704; called by muse, mutect2, varscan2
- DCLK1 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746085515, COSV55176250; called by muse, mutect2, varscan2
- DMD | c.7597G>A p.A2533T | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as rs369583884, CD098168, COSV58896520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.5176C>T p.R1726* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as rs772321133, CM130524, COSV100518383; called by muse, mutect2, varscan2
- EBF3 | c.1309G>A p.V437I (on ENST00000355311 / NM_001375392.1; = p.V428I on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs756108231, COSV62472885; called by muse, mutect2, varscan2
- EFCAB12 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs548363275, COSV58175191; called by mutect2, varscan2
- EPS15 | c.1917C>T p.I639= | Splice Region (SNP) | VAF 23/98 reads (23%) | catalogued as rs148068749; called by muse, mutect2, varscan2
- FAM20A | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56835903; called by muse, mutect2, varscan2
- FMO1 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as rs778028742, COSV61444963; called by muse, mutect2, varscan2
- FRYL | c.5470C>A p.H1824N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99977132; called by muse, mutect2
- GPR19 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60123066; called by muse, mutect2, varscan2
- GRIK2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 99/166 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs376865962; called by muse, mutect2, varscan2
- GTF3C1 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs370190480; called by muse, mutect2, varscan2
- GYPC | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs139780142, CD910525, COSV99391829; called by muse, varscan2
- HUWE1 | c.5201A>G p.E1734G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV53337762; called by muse, mutect2, varscan2
- IGSF3 | c.1636G>A p.A546T (on ENST00000369486 / NM_001007237.3; = p.A566T on NM_001542.4) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as rs138769450; called by muse, mutect2, varscan2
- IL15RA | c.583+1G>A p.X195_splice | Splice Site (SNP) | VAF 16/88 reads (18%) | catalogued as COSV66092394; called by muse, mutect2, varscan2
- INTS13 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs777593850, COSV53901510, COSV53902785; called by muse, mutect2, varscan2
- JAG1 | c.521_522dup p.G175Rfs*12 | Frame Shift Ins (INS) | VAF 42/187 reads (22%) | catalogued as CI003550; called by pindel, varscan2
- KCND3 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56176709; called by muse, mutect2, varscan2
- KCNJ4 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57856420; called by muse, mutect2, varscan2
- KCNMA1 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1465957812; called by muse, mutect2
- KCNN2 | c.1740G>T p.*580Yext*5 (on ENST00000264773; = p.*792Yext*5 on NM_021614.4) | Nonstop Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV53284764; called by muse, mutect2, varscan2
- KIAA1109 | c.11725A>G p.K3909E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.971); catalogued as COSV52665121; called by muse, mutect2, varscan2
- LGR4 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | catalogued as rs1461413137, COSV58725333; called by muse, mutect2, varscan2
- LHB | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765387170, COSV55484424; called by muse, mutect2, varscan2
- MACC1 | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV60541305; called by muse, mutect2, varscan2
- MAP9 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV60903968; called by muse, mutect2
- MCC | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV56725203; called by muse, mutect2, varscan2
- MCM3AP | c.5842G>A p.E1948K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.212); catalogued as rs138113935; called by muse, mutect2, varscan2
- MKNK2 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV51730968; called by muse, mutect2, varscan2
- MUC16 | c.21989C>A p.T7330K | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.636); catalogued as COSV67452129; called by muse, mutect2, varscan2
- NAGPA | c.836T>A p.V279E | Missense Mutation (SNP) | VAF 33/86 reads (38%) | PolyPhen probably damaging (0.986); catalogued as rs762778282, COSV56569466; called by muse, mutect2, varscan2
- NLRP2 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.204); catalogued as rs765646068, COSV54753038; called by muse, mutect2
- NSD2 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs540859268, COSV56395469; called by muse, mutect2
- OR10G7 | c.125T>A p.L42H | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100389962; called by muse, varscan2
- OR10G9 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV66685917; called by muse, mutect2, varscan2
- OR2T3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100613257; called by muse, mutect2, varscan2
- OR52A5 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1207350360, COSV56614503; called by muse, mutect2, varscan2
- OR5M8 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV59115963; called by muse, mutect2, varscan2
- OTUD7B | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 48/172 reads (28%) | catalogued as rs1553777517, COSV64915483; called by muse, mutect2, varscan2
- PAK5 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs749580822, COSV62023084, COSV62028868; called by muse, mutect2, varscan2
- PCDHGA11 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV53912625; called by muse, mutect2, varscan2
- PCNT | c.5411G>A p.R1804Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762385391, COSV64026011; called by muse, mutect2, varscan2
- PCNX3 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV100482648, COSV58418689; called by muse, mutect2, varscan2
- PHKB | c.708G>A p.S236= | Splice Region (SNP) | VAF 29/83 reads (35%) | catalogued as rs768892939, COSV54516537, COSV54533171; called by muse, mutect2, varscan2
- PI15 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200713288, COSV52640149, COSV52643049; called by muse, mutect2, varscan2
- PI4KA | c.3548G>A p.R1183H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs373302183; called by muse, mutect2, varscan2
- PLEKHO2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764736754, COSV60261639; called by muse, mutect2, varscan2
- PPP1R36 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140512732; called by muse, mutect2
- PRAMEF1 | c.1181T>A p.L394Q | Missense Mutation (SNP) | VAF 149/643 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243294287, COSV60006787; called by muse, mutect2, varscan2
- PRKAA2 | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV64802507; called by muse, mutect2, varscan2
- PTPRS | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1205925337, COSV53612972; called by muse, mutect2, varscan2
- RASIP1 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs374430911, COSV99711216; called by muse, mutect2, varscan2
- RBM7 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772778246, COSV64955472; called by muse, mutect2, varscan2
- RELL2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV51836758; called by muse, mutect2, varscan2
- RELN | c.4807C>G p.Q1603E | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs746725268, COSV58988650, COSV58990414; called by muse, mutect2, varscan2
- RNF17 | c.3563G>T p.S1188I | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55035856, COSV99693725; called by muse, mutect2, varscan2
- ROBO1 | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs554782891, COSV71391532; called by muse, mutect2, varscan2
- RP1L1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as rs777820137, COSV61444112; called by muse, mutect2
- RYR3 | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV66781133; called by muse, mutect2, varscan2
- SALL4 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as rs755288586, COSV53850429; called by muse, mutect2, varscan2
- SEMA4B | c.2315T>G p.L772R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100153330; called by muse, mutect2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC6 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1027571676, COSV58432550, COSV58434728; called by muse, mutect2, varscan2
- SLCO4C1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769468689, COSV60513608; called by muse, mutect2, varscan2
- SPDL1 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs143182474, COSV54669985; called by muse, mutect2, varscan2
- SUMF1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1312775449, COSV55992083; called by muse, mutect2, varscan2
- SWT1 | c.2046T>A p.S682R | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62253408; called by muse, mutect2, varscan2
- TANC1 | c.4885A>G p.R1629G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV55084457; called by muse, mutect2, varscan2
- TENM1 | c.3976A>G p.M1326V | Missense Mutation (SNP) | VAF 134/166 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64427064; called by muse, mutect2, varscan2
- TET1 | c.2972C>A p.T991K | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV65382818; called by muse, mutect2, varscan2
- TG | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV55068525, COSV99603781; called by muse, mutect2, varscan2
- TLL1 | c.2075T>G p.F692C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV50265111; called by muse, mutect2, varscan2
- TNXB | c.4555G>A p.V1519M (on ENST00000647633; = p.V1272M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs749925578, COSV64475090; called by muse, mutect2, varscan2
- TP53INP1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.536); catalogued as COSV61330898; called by muse, mutect2
- TRPC5 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 181/228 reads (79%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs754729916, COSV53286063; called by muse, mutect2, varscan2
- TTN | c.34288G>T p.E11430* (on ENST00000591111; = p.E12493* on NM_001267550.2) | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100616895, COSV100634842; called by mutect2, varscan2
- TUT1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.513); catalogued as rs1174156355, COSV53469107; called by muse, mutect2, varscan2
- TWNK | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99272600; called by muse, mutect2
- ZNF443 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 106/791 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); catalogued as rs1372687545, COSV56890682; called by muse, mutect2, varscan2
- ZNF483 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV58514739; called by muse, mutect2, varscan2
- ZNF502 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs778928814, COSV56072713; called by muse, mutect2, varscan2
- APC | c.571dup p.Y191Lfs*2 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.1004del p.R335Lfs*12 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- ARID2 | c.1109dup p.L370Ffs*18 | Frame Shift Ins (INS) | VAF 56/204 reads (27%) | called by mutect2, pindel, varscan2
- DHX15 | c.99_119del p.E34_R40del | In Frame Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- FUBP1 | c.901del p.I301Yfs*22 | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel, varscan2
- KIF27 | c.3668_3669del p.K1223Tfs*2 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- MYO3A | c.3574del p.M1192* | Frame Shift Del (DEL) | VAF 24/176 reads (14%) | called by mutect2, varscan2
- PRAMEF17 | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- RMND5B | c.385dup p.Y129Lfs*138 | Frame Shift Ins (INS) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- SNTG1 | c.820dup p.I274Nfs*18 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- STAT6 | c.479-2_479-1del p.X160_splice | Splice Site (DEL) | VAF 29/223 reads (13%) | called by mutect2, pindel, varscan2
- TMEM108 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2
- ABI1 | c.1461C>T p.V487= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV61015632; called by muse, mutect2, varscan2
- AC092143.1 | c.1575G>A p.T525= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs143029958; called by muse, mutect2, varscan2
- BMPER | c.1221C>T p.N407= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs761577169, COSV51813468, COSV99778678; called by muse, mutect2, varscan2
- C9 | c.1437G>A p.L479= | Silent (SNP) | VAF 92/184 reads (50%) | catalogued as rs756670408, COSV99662130; called by muse, varscan2
- COL6A3 | c.414C>T p.A138= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs148996231; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CPSF4 | c.750G>A p.E250= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99461765; called by muse, mutect2, varscan2
- CRYBG2 | c.3372C>T p.F1124= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs377077531; called by muse, mutect2
- GFRA3 | c.636G>A p.A212= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99218418; called by muse, mutect2
- HTR2C | c.684G>A p.T228= | Silent (SNP) | VAF 58/237 reads (24%) | catalogued as COSV52204051, COSV52218527; called by muse, mutect2, varscan2
- IRX6 | c.993G>A p.S331= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV51859504; called by muse, mutect2, varscan2
- ITGAX | c.2319C>T p.A773= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1016765276, COSV51642692; called by muse, mutect2, varscan2
- KCNA7 | c.624G>A p.P208= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs763785159, COSV55502772, COSV55503106; called by muse, mutect2
- KCNT1 | c.2281C>A p.R761= (on ENST00000488444; = p.R780= on NM_020822.3) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV53697089, COSV99706367; called by muse, mutect2, varscan2
- KIF1B | c.4809C>T p.S1603= (on ENST00000377086 / NM_001365952.1; = p.S1557= on NM_015074.3) | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as rs749686737, COSV55804792; called by muse, mutect2, varscan2
- LCT | c.5382G>A p.A1794= | Silent (SNP) | VAF 79/194 reads (41%) | catalogued as rs1443619474, COSV51545337; called by muse, mutect2, varscan2
- MACROD2 | c.564C>A p.G188= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV53956374; called by muse, mutect2, varscan2
- MUC16 | c.29439G>T p.A9813= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as COSV67452122; called by muse, mutect2, varscan2
- NEB | c.4392C>T p.G1464= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs771527086, COSV50828127; called by muse, mutect2, varscan2
- NOL7 | c.333A>G p.R111= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as COSV63079893; called by muse, mutect2, varscan2
- OSBPL7 | c.2064C>T p.G688= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs368998627; called by muse, mutect2, varscan2
- OSR2 | c.240C>T p.D80= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs765881456, COSV52555868; called by muse, mutect2, varscan2
- PCDHAC2 | c.1815C>T p.T605= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV53837706; called by muse, mutect2, varscan2
- PCDHB15 | c.1746G>A p.P582= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs782181903, COSV50860951, COSV50863528; called by muse, mutect2, varscan2
- PCDHB3 | c.708C>T p.N236= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs782533944, COSV50564702; called by muse, mutect2, varscan2
- PCDHGA2 | c.1722C>T p.G574= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV53912616; called by muse, mutect2, varscan2
- PHF2 | c.720C>T p.C240= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs779567951, COSV63679260; called by muse, mutect2
- PLA2G2C | c.129C>T p.G43= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV56124188; called by muse, mutect2, varscan2
- PNPLA7 | c.588C>T p.D196= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs759504557, COSV52995563; called by muse, mutect2, varscan2
- PXDN | c.1812G>A p.S604= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs772922626, COSV53227557, COSV99412946; called by muse, mutect2, varscan2
- RASAL1 | c.2292C>T p.V764= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV55654415; called by muse, mutect2, varscan2
- SART3 | c.1068C>T p.V356= (on ENST00000228284; = p.V338= on NM_014706.4) | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs756621912, COSV57205989; called by muse, mutect2, varscan2
- SCN4A | c.4617C>T p.D1539= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs772431686, COSV71126791; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHANK2 | c.3471C>T p.F1157= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs556412006, COSV53589158; called by muse, mutect2
- SI | c.3001C>T p.L1001= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV52268780, COSV52269518; called by muse, mutect2, varscan2
- SLC16A14 | c.621G>A p.A207= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs765112155, COSV54617291, COSV54621945; called by muse, mutect2, varscan2
- SNTA1 | c.684C>T p.P228= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV54128280, COSV54128554; called by muse, mutect2, varscan2
- SPACA7 | c.378C>T p.G126= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs140194752; called by muse, mutect2, varscan2
- SPART | c.798C>A p.P266= | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as COSV100768705, COSV62084068; called by muse, mutect2, varscan2
- TRPC6 | c.552G>A p.P184= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as rs201872553, COSV60251766; called by muse, mutect2, varscan2
- TSC22D1 | c.2256A>G p.S752= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as COSV71775326; called by muse, varscan2
- TSHZ2 | c.1830G>A p.A610= | Silent (SNP) | VAF 126/363 reads (35%) | catalogued as rs147016688, COSV61587419; called by muse, mutect2, varscan2
- ZNF326 | c.648C>T p.P216= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs371249300; called by muse, mutect2, varscan2
